Somatic mutation profile of tumor specimen TCGA-UF-A7JF-01A (aliquot TCGA-UF-A7JF-01A-11D-A34J-08) from TCGA case TCGA-UF-A7JF, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 80.7 years (29,468 days).
Specimen TCGA-UF-A7JF-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 7648c244-3b80-4f68-bf2e-d10f8e9481a0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-UF-A7JF-10A (Blood Derived Normal), aliquot TCGA-UF-A7JF-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7235cc1c-74c2-4d4c-90f9-2fbcea94b3f5

The open-access MAF lists 116 somatic variants for this specimen: 84 protein-altering or splice-affecting, 30 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 70, Silent 30, Nonsense Mutation 6, Frame Shift Ins 4, Intron 2, Splice Site 2, Frame Shift Del 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PIK3CA | c.1633G>A p.E545K | Missense Mutation (SNP) | VAF 24/99 reads (24%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.909); catalogued as rs104886003, CM126692, COSV55873239, COSV55878227; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- PTEN | c.406T>C p.C136R | Missense Mutation (SNP) | VAF 47/155 reads (30%) | hotspot (GDC flag); SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as rs786201044, CM004336, COSV100911109, COSV64289087; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- TP53 | c.595G>T p.G199* | Nonsense Mutation (SNP) | VAF 17/64 reads (27%) | catalogued as rs1567551821, COSV52710769, COSV52715098, COSV52760685; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.469G>T p.V157F | Missense Mutation (SNP) | VAF 35/113 reads (31%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs121912654, CM137621, COSV52667015, COSV52676009, COSV52752314, COSV53205488; ClinVar: uncertain significance / likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ABCC4 | c.2798T>C p.L933S | Missense Mutation (SNP) | VAF 63/185 reads (34%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.783); catalogued as COSV100972678; called by muse, mutect2, varscan2
- BHLHE23 | c.351C>A p.N117K (on ENST00000370346; = p.N133K on NM_080606.4) | Missense Mutation (SNP) | VAF 8/40 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100947618, COSV64846334; called by muse, mutect2
- C10orf71 | c.569C>T p.S190F | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100110496; called by muse, mutect2, varscan2
- CACNA2D1 | c.1488T>A p.D496E | Missense Mutation (SNP) | VAF 39/137 reads (28%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV100667043; called by muse, mutect2, varscan2
- CAPN6 | c.1430G>C p.G477A | Missense Mutation (SNP) | VAF 15/26 reads (58%) | SIFT tolerated (0.05); PolyPhen benign (0.108); catalogued as COSV100137000; called by muse, mutect2, varscan2
- CCP110 | c.1514A>G p.H505R | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT tolerated (0.22); PolyPhen benign (0.165); catalogued as rs1362108473, COSV101195319; called by muse, mutect2, varscan2
- CCT8L2 | c.676G>T p.G226W | Missense Mutation (SNP) | VAF 31/142 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.886); catalogued as COSV100742969; called by muse, mutect2, varscan2
- CRISP3 | c.767G>T p.C256F (on ENST00000371159 / NM_001368123.1; = p.C238F on NM_006061.4) | Missense Mutation (SNP) | VAF 30/121 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99539131; called by muse, mutect2, varscan2
- CUX1 | c.3071C>G p.P1024R | Missense Mutation (SNP) | VAF 29/100 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.154); catalogued as COSV99472595; called by muse, mutect2, varscan2
- CXCR4 | c.226T>A p.Y76N | Missense Mutation (SNP) | VAF 60/104 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99603325; called by muse, mutect2, varscan2
- DCHS1 | c.3413G>T p.G1138V | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV100202419; called by muse, mutect2, varscan2
- DNAI3 | c.436C>T p.P146S | Missense Mutation (SNP) | VAF 38/122 reads (31%) | SIFT tolerated (0.59); PolyPhen benign (0.006); catalogued as rs1557710855, COSV54001566, COSV99642185; called by muse, mutect2, varscan2
- DSCAM | c.3340A>G p.K1114E | Missense Mutation (SNP) | VAF 44/137 reads (32%) | SIFT tolerated (0.06); PolyPhen benign (0.089); catalogued as COSV101261158; called by muse, mutect2, varscan2
- EREG | c.328G>A p.V110I | Missense Mutation (SNP) | VAF 62/129 reads (48%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.721); catalogued as COSV99791797; called by muse, mutect2, varscan2
- FAM90A1 | c.1333G>A p.V445I | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.865); catalogued as rs1373189149, COSV100274444; called by muse, mutect2
- FLI1 | c.1057G>T p.G353C | Missense Mutation (SNP) | VAF 18/57 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99857834, COSV99858000; called by muse, mutect2, varscan2
- GHITM | c.746G>A p.G249E | Missense Mutation (SNP) | VAF 16/60 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.701); catalogued as rs1185094676, COSV100930122; called by muse, mutect2, varscan2
- GPR21 | c.751G>T p.A251S | Missense Mutation (SNP) | VAF 97/239 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101016495; called by muse, mutect2, varscan2
- GRIN1 | c.1280A>T p.N427I | Missense Mutation (SNP) | VAF 23/53 reads (43%) | SIFT deleterious (0.01); PolyPhen benign (0.285); catalogued as COSV100160587; called by muse, mutect2, varscan2
- KANK3 | c.2021A>T p.E674V | Missense Mutation (SNP) | VAF 28/81 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.958); catalogued as COSV100035614; called by muse, mutect2, varscan2
- KCNA6 | c.1580C>T p.T527M | Missense Mutation (SNP) | VAF 69/160 reads (43%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.593); catalogued as rs771404375, COSV99768854; called by muse, mutect2, varscan2
- KDSR | c.878A>C p.Q293P | Missense Mutation (SNP) | VAF 16/49 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.917); catalogued as COSV100430309; called by muse, mutect2, varscan2
- KEAP1 | c.1574A>G p.Y525C | Missense Mutation (SNP) | VAF 12/51 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50318396; called by muse, mutect2, varscan2
- KIF21B | c.1976G>A p.R659Q | Missense Mutation (SNP) | VAF 43/167 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV100144928; called by muse, mutect2, varscan2
- LAMB2 | c.1265G>A p.R422H | Missense Mutation (SNP) | VAF 82/177 reads (46%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as rs768933314, COSV59736159; called by muse, mutect2, varscan2
- LEMD3 | c.2033G>A p.R678Q | Missense Mutation (SNP) | VAF 31/115 reads (27%) | SIFT tolerated (0.11); PolyPhen benign (0.08); catalogued as rs770458284, COSV57649144; called by muse, mutect2, varscan2
- LRRCC1 | c.1816G>T p.A606S | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV100835544; called by muse, mutect2, varscan2
- LUM | c.658A>T p.I220F | Missense Mutation (SNP) | VAF 39/131 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.936); catalogued as COSV99899143; called by muse, mutect2, varscan2
- MAP7D2 | c.650A>T p.K217M | Missense Mutation (SNP) | VAF 69/113 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101107490; called by muse, mutect2, varscan2
- MC4R | c.313A>G p.T105A | Missense Mutation (SNP) | VAF 20/128 reads (16%) | SIFT tolerated (0.63); PolyPhen benign (0); catalogued as COSV100236089; called by muse, mutect2, varscan2
- METAP2 | c.152-1G>A p.X51_splice | Splice Site (SNP) | VAF 16/44 reads (36%) | catalogued as COSV54151122; called by muse, mutect2, varscan2
- MLIP | c.844G>C p.D282H | Missense Mutation (SNP) | VAF 33/145 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.078); catalogued as COSV99230108; called by muse, mutect2, varscan2
- MLNR | c.1040G>A p.S347N | Missense Mutation (SNP) | VAF 105/381 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.986); catalogued as rs1161594630, COSV99519990; called by muse, mutect2, varscan2
- MSH2 | c.941A>G p.Q314R | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.53); catalogued as COSV99254379; called by mutect2, varscan2
- MSL3 | c.1292G>A p.W431* (on ENST00000312196 / NM_078629.4; = p.W265* on NM_006800.4) | Nonsense Mutation (SNP) | VAF 92/154 reads (60%) | catalogued as COSV100385002; called by muse, mutect2, varscan2
- NCAPD2 | c.176A>C p.H59P | Missense Mutation (SNP) | VAF 52/264 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100217352; called by muse, mutect2, varscan2
- NEPRO | c.310A>G p.I104V | Missense Mutation (SNP) | VAF 162/390 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs772002800, COSV100075125; called by muse, mutect2, varscan2
- NFIL3 | c.1295A>G p.Y432C | Missense Mutation (SNP) | VAF 44/246 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs978889146, COSV99907011; called by muse, mutect2, varscan2
- NLRP5 | c.1504C>G p.H502D | Missense Mutation (SNP) | VAF 11/50 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV101173826; called by muse, mutect2, varscan2
- NRROS | c.1187G>A p.G396E | Missense Mutation (SNP) | VAF 28/148 reads (19%) | SIFT deleterious (0.03); PolyPhen benign (0.067); catalogued as COSV100145571; called by muse, mutect2, varscan2
- NRXN1 | c.228C>A p.C76* | Nonsense Mutation (SNP) | VAF 15/38 reads (39%) | catalogued as COSV68009964, COSV68033159; called by muse, mutect2, varscan2
- NSD1 | c.5557G>T p.E1853* | Nonsense Mutation (SNP) | VAF 44/93 reads (47%) | catalogued as COSV100729679; called by muse, mutect2, varscan2
- OGDH | c.310C>G p.L104V | Missense Mutation (SNP) | VAF 34/126 reads (27%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV99759403; called by muse, mutect2, varscan2
- OR4A15 | c.471A>T p.Q157H | Missense Mutation (SNP) | VAF 68/228 reads (30%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.346); catalogued as COSV100124287; called by muse, mutect2, varscan2
- OR52E8 | c.64G>C p.G22R | Missense Mutation (SNP) | VAF 55/225 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.875); catalogued as COSV101190696; called by muse, mutect2, varscan2
- OR5K4 | c.172C>A p.P58T | Missense Mutation (SNP) | VAF 125/606 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.931); catalogued as COSV100721383; called by muse, mutect2, varscan2
- PHF14 | c.1177G>C p.G393R | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101301838; called by muse, mutect2, varscan2
- PLCL1 | c.2435A>T p.Y812F | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.99); catalogued as COSV101407233; called by muse, mutect2, varscan2
- PLK3 | c.1289T>A p.V430E | Missense Mutation (SNP) | VAF 46/134 reads (34%) | SIFT tolerated (0.09); PolyPhen benign (0.041); catalogued as COSV100221239; called by muse, mutect2, varscan2
- POLK | c.694+1G>A p.X232_splice | Splice Site (SNP) | VAF 29/54 reads (54%) | catalogued as COSV54031405, COSV99606297; called by muse, mutect2, varscan2
- POMT2 | c.40C>A p.L14M | Missense Mutation (SNP) | VAF 7/25 reads (28%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.241); catalogued as COSV99374558; called by muse, mutect2, varscan2
- PRDM14 | c.1368G>C p.E456D | Missense Mutation (SNP) | VAF 27/113 reads (24%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99400406; called by muse, mutect2, varscan2
- PTPN4 | c.1715G>A p.R572Q | Missense Mutation (SNP) | VAF 33/110 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.097); catalogued as rs200942412; called by muse, mutect2, varscan2
- PTPRS | c.3335C>T p.T1112M | Missense Mutation (SNP) | VAF 46/136 reads (34%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.454); catalogued as rs201447856; called by muse, mutect2, varscan2
- RARG | c.629A>G p.Y210C | Missense Mutation (SNP) | VAF 27/86 reads (31%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV100553614; called by muse, mutect2, varscan2
- RET | c.1447T>G p.Y483D | Missense Mutation (SNP) | VAF 34/98 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as COSV100394252; called by muse, mutect2, varscan2
- SCLT1 | c.1403C>T p.T468M | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.255); catalogued as rs762809545, COSV99828346; called by muse, mutect2, varscan2
- SERPINA9 | c.834G>C p.K278N | Missense Mutation (SNP) | VAF 26/86 reads (30%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.77); catalogued as COSV100098638; called by muse, mutect2, varscan2
- SFXN5 | c.659G>T p.R220L | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99729767; called by muse, mutect2, varscan2
- SPTA1 | c.4055G>T p.S1352I | Missense Mutation (SNP) | VAF 19/89 reads (21%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV63754896; called by muse, mutect2, varscan2
- SREBF2 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 48/69 reads (70%) | SIFT tolerated (0.9); PolyPhen probably damaging (0.992); catalogued as rs1229139236, COSV63332932; called by muse, mutect2, varscan2
- STAT5B | c.1129C>A p.Q377K | Missense Mutation (SNP) | VAF 17/46 reads (37%) | SIFT tolerated (0.58); PolyPhen benign (0.082); catalogued as COSV99511183; called by muse, mutect2, varscan2
- TEX11 | c.2153G>T p.C718F (on ENST00000344304; = p.C703F on NM_031276.3) | Missense Mutation (SNP) | VAF 19/33 reads (58%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100722092; called by muse, mutect2, varscan2
- THBS3 | c.2816C>A p.T939K | Missense Mutation (SNP) | VAF 46/194 reads (24%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.551); catalogued as COSV100104671; called by muse, mutect2, varscan2
- TMTC2 | c.2113G>C p.E705Q | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs1209070575, COSV100338047, COSV58268919; called by muse, mutect2, varscan2
- TRIM42 | c.1905G>T p.M635I | Missense Mutation (SNP) | VAF 37/221 reads (17%) | SIFT tolerated (0.15); PolyPhen benign (0.022); catalogued as COSV99648671; called by muse, mutect2, varscan2
- TRIP12 | c.4314G>A p.W1438* | Nonsense Mutation (SNP) | VAF 52/201 reads (26%) | catalogued as COSV52269908; called by muse, mutect2, varscan2
- TSPAN13 | c.188G>A p.G63D | Missense Mutation (SNP) | VAF 43/175 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100018161; called by muse, mutect2, varscan2
- UGGT1 | c.2035C>T p.Q679* | Nonsense Mutation (SNP) | VAF 43/181 reads (24%) | catalogued as COSV99391003; called by muse, mutect2, varscan2
- WDR5B | c.212A>G p.Y71C | Missense Mutation (SNP) | VAF 72/321 reads (22%) | SIFT tolerated (0.17); PolyPhen benign (0.012); catalogued as COSV58072813; called by muse, mutect2, varscan2
- ZNF160 | c.1443C>G p.F481L | Missense Mutation (SNP) | VAF 57/203 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.171); catalogued as COSV100762434; called by muse, mutect2, varscan2
- ZNF462 | c.5111A>T p.Y1704F | Missense Mutation (SNP) | VAF 23/94 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV52951508, COSV99472868; called by muse, mutect2, varscan2
- ZNF519 | c.362A>G p.Y121C | Missense Mutation (SNP) | VAF 50/95 reads (53%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as COSV101645585; called by muse, mutect2, varscan2
- AJUBA | c.230_233del p.R77Pfs*164 | Frame Shift Del (DEL) | VAF 9/17 reads (53%) | called by mutect2, varscan2
- ARFGEF2 | c.3361dup p.Y1121Lfs*24 | Frame Shift Ins (INS) | VAF 59/182 reads (32%) | called by mutect2, pindel, varscan2
- CLCC1 | c.1603dup p.R535Kfs*54 (on ENST00000356970 / NM_001377464.1; = p.R485Kfs*54 on NM_015127.5) | Frame Shift Ins (INS) | VAF 29/136 reads (21%) | called by mutect2, pindel, varscan2
- DSEL | c.2648dup p.N884Qfs*3 | Frame Shift Ins (INS) | VAF 32/188 reads (17%) | called by mutect2, varscan2
- KIF26B | c.1937G>A p.R646Q | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT deleterious (0.01); PolyPhen benign (0.441); called by muse, mutect2
- MAP3K14 | c.109_110del p.S37Lfs*6 | Frame Shift Del (DEL) | VAF 15/82 reads (18%) | called by pindel, varscan2
- OTOS | c.226dup p.L76Pfs*56 | Frame Shift Ins (INS) | VAF 15/77 reads (19%) | called by mutect2, pindel, varscan2
- ANO2 | c.1722G>C p.R574= (on ENST00000356134 / NM_001278597.3; = p.R578= on NM_001278596.3) | Silent (SNP) | VAF 13/72 reads (18%) | catalogued as COSV100501869; called by muse, mutect2, varscan2
- CHTOP | c.666A>G p.A222= | Silent (SNP) | VAF 36/94 reads (38%) | catalogued as COSV100904703; called by muse, mutect2, varscan2
- CLMN | c.939C>T p.R313= | Silent (SNP) | VAF 29/126 reads (23%) | catalogued as COSV100112756; called by muse, mutect2, varscan2
- CNTNAP5 | c.2595T>A p.S865= | Silent (SNP) | VAF 59/196 reads (30%) | catalogued as COSV101443901; called by muse, mutect2, varscan2
- CTSL | c.300C>A p.P100= | Silent (SNP) | VAF 20/140 reads (14%) | catalogued as COSV100446721; called by muse, mutect2, varscan2
- DBX1 | c.783G>A p.P261= | Silent (SNP) | VAF 10/38 reads (26%) | catalogued as COSV57054257; called by muse, mutect2
- DHX37 | c.2556C>T p.L852= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as rs200490767, COSV58138422; called by muse, mutect2, varscan2
- FCER1A | c.570C>T p.L190= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as COSV63667496; called by muse, mutect2, varscan2
- GAB4 | c.516C>G p.L172= | Silent (SNP) | VAF 6/18 reads (33%) | catalogued as rs777152427, COSV101272063; called by muse, varscan2
- HBD | c.336G>T p.V112= | Silent (SNP) | VAF 24/101 reads (24%) | catalogued as COSV99496822; called by muse, mutect2, varscan2
- HMX2 | c.723G>A p.P241= | Silent (SNP) | VAF 3/15 reads (20%) | catalogued as rs139853496; called by muse, mutect2
- IGHG1 | c.591G>A p.L197= | Silent (SNP) | VAF 143/566 reads (25%) | called by muse, mutect2, varscan2
- KATNA1 | c.1122G>A p.E374= | Silent (SNP) | VAF 35/80 reads (44%) | catalogued as COSV100167938; called by muse, mutect2, varscan2
- KIF1B | c.3387C>T p.I1129= (on ENST00000377086 / NM_001365952.1; = p.I1083= on NM_015074.3) | Silent (SNP) | VAF 59/195 reads (30%) | catalogued as COSV99823906; called by muse, mutect2, varscan2
- KLHL14 | c.1308C>T p.G436= | Silent (SNP) | VAF 8/50 reads (16%) | catalogued as rs1397148907, COSV100839281; called by muse, mutect2
- MFSD14A | c.570G>C p.V190= | Silent (SNP) | VAF 39/137 reads (28%) | catalogued as COSV100924616; called by muse, mutect2, varscan2
- NRXN1 | c.555T>A p.R185= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as COSV101278890; called by muse, mutect2, varscan2
- OR10Z1 | c.246C>T p.L82= | Silent (SNP) | VAF 73/229 reads (32%) | catalogued as COSV100779060, COSV63525853; called by muse, mutect2, varscan2
- PHF21B | c.648C>G p.P216= | Silent (SNP) | VAF 30/46 reads (65%) | catalogued as rs1166148097, COSV100504017, COSV57558469; called by muse, mutect2, varscan2
- POMT2 | c.39G>A p.E13= | Silent (SNP) | VAF 7/25 reads (28%) | catalogued as COSV99374560; called by muse, mutect2, varscan2
- RYR2 | c.6390G>C p.L2130= | Silent (SNP) | VAF 19/56 reads (34%) | catalogued as rs777550265, COSV100772109, COSV63712118; called by muse, mutect2, varscan2
- RYR3 | c.6192C>G p.G2064= | Silent (SNP) | VAF 36/138 reads (26%) | catalogued as COSV101213592; called by muse, mutect2, varscan2
- SGSH | c.1158C>T p.L386= | Silent (SNP) | VAF 40/120 reads (33%) | catalogued as rs765011477, COSV100413552, COSV58338386; called by muse, mutect2, varscan2
- ST8SIA5 | c.282G>A p.A94= | Silent (SNP) | VAF 15/85 reads (18%) | catalogued as rs371174943; called by muse, mutect2, varscan2
- TET3 | c.1662T>A p.P554= | Silent (SNP) | VAF 12/32 reads (38%) | catalogued as COSV99996542; called by muse, mutect2, varscan2
- TNFSF13 | c.399G>A p.V133= | Silent (SNP) | VAF 33/109 reads (30%) | catalogued as COSV99547109; called by muse, mutect2, varscan2
- WNT3 | c.297C>T p.A99= | Silent (SNP) | VAF 20/44 reads (45%) | catalogued as COSV99843375; called by muse, mutect2, varscan2
- ZBTB10 | c.1080A>G p.K360= | Silent (SNP) | VAF 12/107 reads (11%) | catalogued as rs1299228371, COSV100990270; called by muse, mutect2, varscan2
- ZNF329 | c.1626A>G p.*542= | Silent (SNP) | VAF 60/176 reads (34%) | catalogued as COSV100798796; called by muse, mutect2, varscan2
- ZNF672 | c.933C>T p.F311= | Silent (SNP) | VAF 17/41 reads (41%) | catalogued as rs751755684, COSV60638503; called by muse, mutect2, varscan2
- ARMC8 | c.1134+33G>T | Intron (SNP) | VAF 24/91 reads (26%) | catalogued as COSV100627798; called by muse, mutect2, varscan2
- PTPRM | c.2527+251A>G | Intron (SNP) | VAF 173/320 reads (54%) | catalogued as rs527524261, COSV59849816; called by muse, mutect2, varscan2
